Somatic mutation profile of tumor specimen MMRF_1261_1_BM_CD138pos (aliquot MMRF_1261_1_BM_CD138pos_T1_KAS5U_L00344) from MMRF case MMRF_1261, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,888 days).
Specimen MMRF_1261_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 968a91a0-277a-4815-a4e6-77642ed6f22f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1261_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1261_1_PB_Whole_C2_KAS5U_L00345; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5e57e9d-f6f7-4bd3-b958-3ff1cbbe6209

The open-access MAF lists 186 somatic variants for this specimen: 74 protein-altering or splice-affecting, 19 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, 3'UTR 49, Intron 26, Silent 19, 3'Flank 6, RNA 6, 5'UTR 5, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF28 | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs1037406882; called by muse, mutect2, varscan2
- BEST3 | c.1576A>T p.I526F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs376818699; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.207); catalogued as COSV58115968; called by muse, mutect2, varscan2
- CELA3B | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs374748425; called by muse, mutect2, varscan2
- CYP24A1 | c.464G>T p.W155L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as CM1510866; called by muse, mutect2
- EMC4 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV99970852; called by muse, mutect2, varscan2
- IGKV4-1 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs541963022; called by muse, varscan2
- MAN2A1 | c.1163dup p.E389Rfs*38 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs1364182780; called by pindel, varscan2
- MGARP | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1286480063; called by muse, mutect2, varscan2
- NOP14 | c.1916G>C p.R639T | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV58624918; called by muse, mutect2, varscan2
- POU2F2 | c.703G>T p.D235Y (on ENST00000526816 / NM_001207025.3; = p.D219Y on NM_002698.5) | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60762339; called by muse, mutect2, varscan2
- RBPJL | c.1441G>C p.V481L | Missense Mutation (SNP) | VAF 135/262 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs754503250, COSV59213521; called by muse, mutect2, varscan2
- TAFA5 | c.179C>T p.T60M (on ENST00000402357 / NM_001082967.3; = p.T53M on NM_015381.7) | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as rs373045207; called by muse, mutect2, varscan2
- TBXA2R | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200152113, COSV64344262; called by muse, mutect2, varscan2
- TET3 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as rs760754169; called by muse, mutect2, varscan2
- THBS2 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs368102843; called by muse, mutect2, varscan2
- TLR5 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.666); catalogued as COSV60559266; called by muse, mutect2, varscan2
- TMPRSS15 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750449733, COSV53044658; called by muse, mutect2, varscan2
- TRAPPC12 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs781644053; called by muse, mutect2, varscan2
- ARID2 | c.4396del p.S1466Vfs*2 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | called by mutect2, pindel, varscan2
- BMPR1B | c.1352C>G p.P451R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT7 | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CD1E | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CEP120 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDN19 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- CLUH | c.862C>G p.Q288E (on ENST00000435359; = p.Q326E on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- COL9A3 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CSTB | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.137); called by muse, mutect2
- CYLC1 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CYP2C19 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DNAJC13 | c.3310A>G p.I1104V | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB8 | c.2871C>A p.D957E | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EMC8 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- EML6 | c.4735T>A p.Y1579N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2
- EYA4 | c.1802A>T p.K601I (on ENST00000531901 / NM_001301013.1; = p.K595I on NM_004100.5) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- FAT2 | c.10964T>A p.L3655H | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRMD4B | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FSTL1 | c.64-2A>C p.X22_splice | Splice Site (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- GLUD1 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GSK3A | c.687C>A p.F229L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- HERC2P9 | n.4401+1G>T | Splice Site (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- HOATZ | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, varscan2
- HSPA9 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KAT7 | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNH3 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEL2 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MARS1 | c.826A>T p.N276Y | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MGAM2 | c.4535G>T p.G1512V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGAT5 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYBL2 | c.954C>G p.D318E | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NAP1L3 | c.663_704del p.E222_K235del | In Frame Del (DEL) | VAF 59/62 reads (95%) | called by muse*, mutect2, varscan2*
- NFKBIA | c.738_740dup p.T247dup | In Frame Ins (INS) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- NPL | c.691T>A p.L231M | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- NR1D2 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- NXPE2 | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PADI4 | c.1234G>T p.V412L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- PATL2 | c.1373T>A p.I458K | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PAXBP1 | c.203_221del p.T68Rfs*16 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel
- PCDHGA8 | c.272A>C p.D91A | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE3B | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- PPP1R18 | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 133/432 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASIP1 | c.2509A>T p.N837Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAMD9L | c.269T>G p.L90* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- SCARA5 | c.643A>C p.I215L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA5 | c.1171T>G p.F391V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCERG1 | c.2791T>A p.W931R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TGDS | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 79/80 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TPD52L2 | c.21T>A p.D7E | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TRAF3 | c.980_1005del p.A327Gfs*54 | Frame Shift Del (DEL) | VAF 28/34 reads (82%) | called by mutect2, pindel, varscan2
- TRIM2 | c.2064G>C p.W688C (on ENST00000437508; = p.W715C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- XPO5 | c.2551C>G p.L851V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- YTHDC2 | c.2839T>G p.S947A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF407 | c.5477C>A p.T1826N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- AJAP1 | c.249G>A p.P83= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs754091872, COSV65451362; called by muse, mutect2, varscan2
- CCDC69 | c.315G>C p.L105= | Silent (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- CNTRL | c.3804C>T p.P1268= | Silent (SNP) | VAF 80/166 reads (48%) | called by muse, mutect2, varscan2
- EFTUD2 | c.882T>G p.T294= | Silent (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- FAM135A | c.4149A>G p.S1383= (on ENST00000370479 / NM_001351599.1; = p.S1170= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs770068660; called by muse, mutect2, varscan2
- FGD5 | c.2262G>A p.L754= | Silent (SNP) | VAF 104/222 reads (47%) | called by muse, mutect2, varscan2
- FRRS1 | c.120T>C p.G40= | Silent (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- IGDCC4 | c.360G>A p.S120= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs764813803; called by muse, mutect2, varscan2
- ITPR3 | c.2484C>T p.N828= | Silent (SNP) | VAF 102/164 reads (62%) | called by muse, mutect2, varscan2
- LIMD2 | c.282G>A p.Q94= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV51992487; called by muse, mutect2, varscan2
- MAN2A1 | c.1164A>G p.P388= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, varscan2
- NEU1 | c.753C>T p.Y251= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs780368958; called by muse, mutect2, varscan2
- RAB11FIP5 | c.222C>T p.S74= | Silent (SNP) | VAF 56/115 reads (49%) | catalogued as rs754500299; called by muse, mutect2
- SLC2A7 | c.1389C>T p.Y463= | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as rs746573210, COSV101280823; called by muse, mutect2, varscan2
- SRRM1 | c.2259C>G p.V753= | Silent (SNP) | VAF 72/124 reads (58%) | called by muse, mutect2, varscan2
- TBC1D14 | c.738A>G p.R246= | Silent (SNP) | VAF 85/162 reads (52%) | called by muse, mutect2, varscan2
- USH2A | c.12852C>T p.S4284= | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2
- USH2A | c.4074A>T p.G1358= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as COSV100232977, COSV100243171; called by muse, mutect2, varscan2
- ZNF652 | c.1590C>T p.I530= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as rs201480190; called by muse, mutect2, varscan2
- AC073310.1 | n.231G>A | RNA (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- AKR1B10 | c.*4T>A | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- AKR1B10 | c.*5G>T | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- AP002414.4 | n.1043G>T | RNA (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- AP002414.4 | n.1042G>T | RNA (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- ATP11C | c.*419del | 3'UTR (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- BLOC1S6 | c.*1258C>G | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2
- C19orf54 | c.*162C>A | 3'UTR (SNP) | VAF 12/149 reads (8%) | called by muse, mutect2
- C22orf15 | c.436-288A>C | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- C3orf49 | c.849+43T>C | Intron (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2
- CA3 | c.*211G>C | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- CCL5 | c.-172G>A | 5'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as rs1286498307; called by muse, mutect2, varscan2
- CFAP57 | c.2247+13G>T | Intron (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- CSPG5 | c.98-100G>C | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- DGKG | c.*2323C>T | 3'UTR (SNP) | VAF 29/52 reads (56%) | catalogued as rs973367141, COSV53961534; called by muse, mutect2, varscan2
- DMTN | c.*911C>A | 3'UTR (SNP) | VAF 72/174 reads (41%) | called by muse, mutect2, varscan2
- DNM1 | c.1336-89C>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- DNM1P35 | n.210G>A | RNA (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- DOK1 | c.-113G>T | 5'UTR (SNP) | VAF 33/63 reads (52%) | catalogued as rs1032239237; called by muse, mutect2, varscan2
- DRGX | c.*789A>T | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- ELFN2 | c.*4686C>A | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- EPB41L4A | c.*2223C>T | 3'UTR (SNP) | VAF 48/79 reads (61%) | catalogued as rs1049294193; called by muse, mutect2, varscan2
- EPB41L4A | chr5:112420320 G>T | 5'Flank (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- EPHB1 | c.*647T>A | 3'UTR (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- ERN1 | c.-54C>T | 5'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as rs1475886975, COSV70502799; called by muse, mutect2, varscan2
- FAM204A | chr10:118307695 T>A | 3'Flank (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- FYCO1 | c.*2585A>G | 3'UTR (SNP) | VAF 30/52 reads (58%) | catalogued as rs953176567; called by muse, mutect2, varscan2
- GPM6A | c.*703G>A | 3'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- GRIP1 | c.-139C>G | 5'UTR (SNP) | VAF 94/197 reads (48%) | called by muse, mutect2, varscan2
- HECTD4 | c.2743-51C>T | Intron (SNP) | VAF 47/93 reads (51%) | catalogued as rs192252568; called by muse, mutect2, varscan2
- HLA-V | n.4309T>A | RNA (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176173933 C>A | 3'Flank (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.314+40T>C | Intron (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- HSPB6 | c.*622C>A | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- IGSF10 | c.*1350G>A | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- INSYN2A | c.*1952C>A | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- IRAK4 | chr12:43788100 T>A | 3'Flank (SNP) | VAF 29/74 reads (39%) | called by muse, varscan2
- KLB | c.*2064G>T | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- LY6H | c.68-49G>C | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- MARCHF8 | c.*3010A>G | 3'UTR (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- MFRP | chr11:119341325 G>T | 3'Flank (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- NCKAP1L | c.*599C>T | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*3582C>T | 3'UTR (SNP) | VAF 35/79 reads (44%) | catalogued as rs867525766; called by muse, mutect2, varscan2
- NKAPD1 | c.375-61T>G | Intron (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- NKIRAS1 | chr3:23890844 T>C | 3'Flank (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- NNAT | c.*390T>G | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- NUDT18 | c.377-38A>T | Intron (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- OSBPL2 | c.783-23A>T | Intron (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- OST4 | c.*86C>G | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- PAMR1 | c.-16A>C | 5'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- PFDN6 | chr6:33295831 G>T | 3'Flank (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.*409A>T | 3'UTR (SNP) | VAF 58/112 reads (52%) | called by muse, mutect2, varscan2
- POGLUT3 | c.*2615T>C | 3'UTR (SNP) | VAF 36/55 reads (65%) | called by muse, mutect2, varscan2
- PRPF31 | c.856-27T>C | Intron (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
- PSPC1 | c.*347T>C | 3'UTR (SNP) | VAF 55/98 reads (56%) | called by muse, mutect2, varscan2
- PTER | c.698+91C>G | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs1450162562; called by muse, mutect2, varscan2
- PTGS1 | c.*577G>A | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- QKI | c.935-877A>C | Intron (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- RETREG2 | c.*2685A>G | 3'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- RIMS4 | c.*3815G>A | 3'UTR (SNP) | VAF 71/114 reads (62%) | catalogued as rs566276436; called by muse, mutect2, varscan2
- SCN4B | c.*1041G>C | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- SIAH3 | c.*778G>C | 3'UTR (SNP) | VAF 42/43 reads (98%) | called by muse, mutect2, varscan2
- SLC12A9 | c.758-36G>A | Intron (SNP) | VAF 43/69 reads (62%) | called by muse, mutect2, varscan2
- SLC17A3 | c.304-186T>C | Intron (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- SLC1A4 | c.*830_*831del | 3'UTR (DEL) | VAF 35/67 reads (52%) | called by mutect2, pindel, varscan2
- SLC24A3 | c.*207C>T | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2
- SMARCC1 | c.*1910T>A | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- SMARCC1 | c.*1908T>G | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2
- SMIM7 | c.212+1531A>T | Intron (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- SORL1 | c.*97T>A | 3'UTR (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- SPRY1 | c.*1128T>A | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- SRRT | c.2429-16C>A | Intron (SNP) | VAF 71/122 reads (58%) | called by muse, mutect2, varscan2
- ST7L | c.1629+93A>G | Intron (SNP) | VAF 52/88 reads (59%) | called by muse, mutect2, varscan2
- SVIL | c.-201+32128G>A | Intron (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- TANK | c.327+52G>C | Intron (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99376545; called by muse, mutect2
- TBL1XR1 | c.*5977C>T | 3'UTR (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- TM2D3 | c.170-467G>C | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- TMEM222 | c.*906G>C | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- TMPO | c.*2066T>A | 3'UTR (SNP) | VAF 38/75 reads (51%) | catalogued as rs566682934; called by muse, mutect2, varscan2
- TMPRSS13 | c.*430C>G | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2
- TPMT | c.*992C>G | 3'UTR (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- TPT1 | c.400-173A>C | Intron (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2
- TRIM37 | c.2696-22T>A | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- TTC38 | c.735+314C>A | Intron (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*544_*546del | 3'UTR (DEL) | VAF 38/126 reads (30%) | called by pindel, varscan2
- UTP23 | c.*169C>T | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- WNT9A | c.*50G>A | 3'UTR (SNP) | VAF 56/122 reads (46%) | catalogued as rs116334651, COSV55294560; called by muse, mutect2, varscan2
- YWHAE | c.*576T>A | 3'UTR (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.*566C>T | 3'UTR (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- ZNF271P | n.1706G>T | RNA (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- ZNF490 | c.*1750A>G | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ZNF600 | c.*160C>A | 3'UTR (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.1180+1511C>T | Intron (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
